Somatic mutation profile of tumor specimen BA3308D (aliquot aq-BA3308D) from BEATAML1.0 case 2772, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 78.8 years (28,766 days).
Specimen BA3308D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0eca8d3e-9a68-43fa-9c7a-a40e81ce3629.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3383D (Solid Tissue Normal), aliquot aq-BA3383D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cdd84a5-dc36-4583-bf19-2fdb39f15b15

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RUNX1 | c.405G>C p.R135S (on ENST00000344691 / NM_001001890.3; = p.R162S on NM_001754.5) | Missense Mutation (SNP) | VAF 90/108 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519749, COSV100277991, COSV55879245; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CRTC1 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1245831619; called by muse, mutect2
- ESYT1 | c.2309C>G p.P770R | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0.265); catalogued as COSV57275141; called by muse, mutect2, varscan2
- DOCK10 | c.4586A>T p.N1529I | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- NEO1 | c.1176_1177insGCCCTTGG p.H393Afs*12 | Frame Shift Ins (INS) | VAF 28/86 reads (33%) | called by mutect2, varscan2
- SMC1A | c.3031_3032insGAGGTAGGG p.N1011delinsRGRD | In Frame Ins (INS) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- TENM3 | c.5323C>T p.L1775F | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
